TCGA case TCGA-29-1710 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4261267c-7042-4c6e-83ed-12fb401003fc

Demographics
Sex at birth: female; Race: white; Age at index: 54 years; Vital status: Dead; Days to death: 951 days (2.6 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 54.7 years (19,969 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Days to treatment end: 52 days; Treatment dose: 1,870 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Days to treatment end: 52 days; Number of cycles: 2; Treatment dose: 260 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Days to treatment end: 52 days; Number of cycles: 2; Treatment dose: 300 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 88 days; Days to treatment end: 150 days; Number of cycles: 4; Treatment dose: 2,790 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 88 days; Days to treatment end: 150 days; Number of cycles: 4; Treatment dose: 1,200 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 322 days; Days to treatment end: 437 days (1.2 years); Number of cycles: 5; Treatment dose: 70 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 468 days (1.3 years); Days to treatment end: 542 days (1.5 years); Number of cycles: 3; Treatment dose: 1,410 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 556 days (1.5 years); Days to treatment end: 580 days (1.6 years); Number of cycles: 2; Treatment dose: 700 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Pan-VEGFR/TIE2 Tyrosine Kinase Inhibitor CEP-11981; Initial disease status: Progressive Disease; Days to treatment start: 619 days (1.7 years); Days to treatment end: 653 days (1.8 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 682 days (1.9 years); Days to treatment end: 766 days (2.1 years); Number of cycles: 5; Treatment dose: 310 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 780 days (2.1 years); Days to treatment end: 853 days (2.3 years); Number of cycles: 3; Treatment dose: 7 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 55.5 years (20,284 days); Days to diagnosis: 315 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 878 days (2.4 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 315 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 315 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 889 days (2.4 years); Disease response: With Tumor.
- Days to follow up: 951 days (2.6 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-1710-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.8; Intermediate dimension: 1.1; Shortest dimension: 0.4.
  Slide TCGA-29-1710-01A-01-BS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 10.
  Slide TCGA-29-1710-01A-02-BS2: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0; Percent lymphocyte infiltration: 15.
- Sample TCGA-29-1710-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-29-1710-02A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 30.
  Slide TCGA-29-1710-02A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 30.
- Sample TCGA-29-1710-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 6: Therapy regimen: Progression.
- Drug treatment 8: Pharmaceutical therapy drug name: CEP 11981; Therapy regimen: Progression.
- Drug treatment 10: Pharmaceutical therapy drug name: Doxorubincin HCL; Therapy regimen: Progression.
- Drug treatment 11: Pharmaceutical therapy drug name: Gemcitabine HCL; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 951 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 951 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 315 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-1710-01A-02D-0559-01): tumor purity 0.47, ploidy 3.06, whole-genome doublings 1.
